Gene-level copy-number profile of tumor specimen TCGA-L7-A56G-01A from TCGA case TCGA-L7-A56G, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 66.0 years (24,106 days).
Specimen TCGA-L7-A56G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ca7ababa-4e41-4228-844d-67814c212ea4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L7-A56G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1950d2f0-38db-4713-8af9-d6c7a247c142

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 193; copy number 2: 18,664; copy number 3: 21,195; copy number 4: 12,439; copy number 5: 3,832; copy number 6: 2,393; copy number 7: 17; copy number 8: 112; copy number 10: 768; copy number 11: 14; copy number 12: 73; copy number 14: 70; copy number 30: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L7-A56G-01A-21D-A25X-01): tumor purity 0.55, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:974,133–1,495,933, 3 genes (within-gene range 0–8): AC004803.1, ERC1, HTR1DP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,098 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:103,855,829–105,438,513, 38 genes, copy number 8: AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1.
- chr8:135,742,343–139,463,016, 17 genes, copy number 7: RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1.
- chr9:6,720,863–7,175,648, 1 gene, copy number 10 (within-gene range 4–10): KDM4C.
- chr9:6,902,670–7,203,458, 2 genes, copy number 10: AL513412.1, AL161443.1.
- chr9:8,314,246–10,612,723, 7 genes, copy number 11 (within-gene range 4–14): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:9,799,423–9,803,784, 1 gene, copy number 14: AL513422.1.
- chr9:13,274,510–15,307,360, 30 genes, copy number 11–14 (within-gene range 2–36): AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr11:67,812,557–71,252,577, 90 genes, copy number 14–30 (within-gene range 2–30) (broad region; genes not listed).
- chr12:66,767–990,053, 24 genes, copy number 8 (within-gene range 0–8): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr12:1,380,060–34,249,958, 823 genes, copy number 8–12 (broad region; genes not listed).
- chr19:15,221,015–16,328,685, 65 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 185. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
